Somatic mutation profile of tumor specimen TARGET-10-PATFYZ-09A (aliquot TARGET-10-PATFYZ-09A-01D) from TARGET case TARGET-10-PATFYZ, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 15.4 years (5,624 days).
Specimen TARGET-10-PATFYZ-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 229e6460-d72b-4ed3-901e-0f3f532ccd8a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATFYZ-10A (Blood Derived Normal), aliquot TARGET-10-PATFYZ-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fd7c48c3-74b0-47e9-b21a-66e3f0681bd6

The open-access MAF lists 26 somatic variants for this specimen: 17 protein-altering or splice-affecting, 1 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Intron 6, Nonsense Mutation 2, Frame Shift Ins 2, 5'UTR 1, In Frame Ins 1, Silent 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP2B2 | c.172C>T p.R58W | Missense Mutation (SNP) | VAF 36/71 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); catalogued as rs762455685, COSV59491447; called by muse, mutect2, varscan2
- CBX8 | c.696C>G p.D232E | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs376248661, COSV53935673; called by muse, mutect2, varscan2
- GRM8 | c.898A>G p.S300G | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV58809815; called by muse, mutect2, varscan2
- PCDHA2 | c.571T>C p.S191P | Missense Mutation (SNP) | VAF 40/93 reads (43%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.067); catalogued as COSV65365507; called by muse, mutect2, varscan2
- PHF6 | c.890G>A p.C297Y | Missense Mutation (SNP) | VAF 14/15 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59700245; called by muse, mutect2, varscan2
- PRLHR | c.548T>C p.I183T | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.036); catalogued as rs1161324361, COSV53303144; called by muse, mutect2, varscan2
- PXDN | c.1852C>T p.R618* | Nonsense Mutation (SNP) | VAF 17/84 reads (20%) | catalogued as rs762639846, COSV53228687; called by muse, mutect2, varscan2
- QSER1 | c.4940_4941insTGGACGCAATCC p.R1647delinsSGRNP (on ENST00000399302; = p.R1776delinsSGRNP on NM_001076786.3) | In Frame Ins (INS) | VAF 10/26 reads (38%) | catalogued as COSV67899797; called by mutect2, pindel, varscan2
- SERINC3 | c.17G>T p.G6V | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as COSV54855769; called by muse, mutect2, varscan2
- SLC17A7 | c.121C>G p.P41A | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.506); catalogued as COSV55546823; called by muse, mutect2, varscan2
- SNAPC4 | c.3659G>T p.G1220V | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as COSV53731350; called by muse, mutect2, varscan2
- ST6GALNAC2 | c.712G>A p.V238M | Missense Mutation (SNP) | VAF 16/30 reads (53%) | PolyPhen benign (0.17); catalogued as COSV56570796; called by muse, mutect2
- STEAP4 | c.868C>T p.R290* | Nonsense Mutation (SNP) | VAF 56/127 reads (44%) | catalogued as rs772041491, COSV57328408; called by muse, mutect2, varscan2
- TBL3 | c.425A>G p.Y142C | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60340882; called by muse, mutect2, varscan2
- ZNF556 | c.721A>G p.S241G | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.579); catalogued as COSV56911230; called by muse, mutect2, varscan2
- IGHV3-64 | c.353_354insTAATTTAGAG p.R118Sfs*? | Frame Shift Ins (INS) | VAF 8/52 reads (15%) | called by mutect2, pindel
- PCDH7 | c.2826dup p.S943Ifs*2 | Frame Shift Ins (INS) | VAF 25/97 reads (26%) | called by mutect2, pindel, varscan2
- IGSF9B | c.2394C>T p.D798= | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as rs376960993; called by muse, mutect2, varscan2
- BCAN | c.2210-45C>T | Intron (SNP) | VAF 9/43 reads (21%) | called by muse, mutect2, varscan2
- CSMD3 | c.178+59854A>T | Intron (SNP) | VAF 23/53 reads (43%) | called by muse, mutect2, varscan2
- IGHV3-20 | chr14:106210935 ins ATCC | 3'Flank (INS) | VAF 16/33 reads (48%) | called by mutect2, pindel, varscan2
- NAV2 | c.-168G>A | 5'UTR (SNP) | VAF 6/16 reads (38%) | catalogued as COSV100643466; called by muse, mutect2, varscan2
- NCAM1 | c.2131+2734G>T | Intron (SNP) | VAF 24/53 reads (45%) | called by muse, mutect2, varscan2
- PIGX | c.532+149T>C | Intron (SNP) | VAF 10/20 reads (50%) | called by muse, mutect2, varscan2
- SRL | c.62-3037G>A | Intron (SNP) | VAF 33/53 reads (62%) | catalogued as rs930677585; called by muse, mutect2, varscan2
- TGM2 | c.1616-167G>A | Intron (SNP) | VAF 22/54 reads (41%) | catalogued as rs773699013; called by muse, mutect2
